Gene-level copy-number profile of specimen HCM-BROD-0478-C16-85M from HCMI case HCM-BROD-0478-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 61.8 years (22,576 days).
Specimen HCM-BROD-0478-C16-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2d64dd48-a81c-45a7-a654-f1e49a88adbb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0478-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,862 have no estimate.
https://portal.gdc.cancer.gov/files/b9d87e3c-f216-426e-8fef-0c9f806c4f4d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 252; copy number 1: 7,098; copy number 2: 39,672; copy number 3: 10,483; copy number 4: 983; copy number 5: 259; copy number 6: 2; copy number 8: 2; copy number 10: 6; copy number 11: 2; copy number 14: 2.

Homozygous deletions (total copy number 0; autosomes only): 252 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:629,062–630,683, 2 genes (within-gene range 0–1): MTND1P23, MTND2P28.
- chr1:633,535–778,626, 9 genes: MTATP8P1, MTATP6P1, MTCO3P12, WBP1LP6, OR4F16, CICP3, AL669831.1, RNU6-1199P, AL669831.2.
- chr2:42,826,322–43,596,046, 13 genes: CHORDC1P1, AC016735.1, LINC01819, LINC02590, RNU6-242P, LINC02580, AC010883.3, ZFP36L2, LINC01126, AC010883.1, THADA, RNU6-958P, RN7SL531P.
- chr4:68,614,419–68,616,137, 2 genes (within-gene range 0–1): AC147055.2, AC147055.4.
- chr12:6,867,119–11,176,016, 226 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 273 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:223,976,146–223,976,249, 1 gene, copy number 6: RNU6-1319P.
- chr3:186,567,403–195,620,233, 165 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:195,746,765–198,123,232, 93 genes, copy number 5 (broad region; genes not listed).
- chr8:127,072,694–127,227,541, 1 gene, copy number 10 (within-gene range 4–10): CASC19.
- chr8:127,289,817–127,742,951, 7 genes, copy number 8–10: CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC.
- chr16:32,250,620–32,255,922, 2 genes, copy number 14: AC133485.3, TP53TG3D.
- chr16:32,289,547–32,380,049, 3 genes, copy number 5–11: AC133548.2, AC133548.1, ACTR3BP3.
- chr16:32,475,051–32,478,250, 1 gene, copy number 6: ABCD1P3.

Autosomal genes at a single copy (total copy number 1): 4,400. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
